Somatic mutation profile of tumor specimen TCGA-EM-A3SX-01A (aliquot TCGA-EM-A3SX-01A-11D-A22Z-08) from TCGA case TCGA-EM-A3SX, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 28.6 years (10,447 days).
Specimen TCGA-EM-A3SX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c3097e9-7946-4ec0-bd0c-71f88e68707f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3SX-10A (Blood Derived Normal), aliquot TCGA-EM-A3SX-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8bc7095a-4815-4103-ba2f-241f5925413e

The open-access MAF lists 31 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 22, Silent 5, Nonsense Mutation 2, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- AFM | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs1330461247, COSV99889027; called by muse, mutect2, varscan2
- BCAN | c.2588G>A p.R863H | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100228318; called by muse, mutect2
- CNTN5 | c.3116G>C p.G1039A | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs750623368, COSV99679425; called by muse, mutect2, varscan2
- DOCK10 | c.1736C>T p.S579L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99290773; called by muse, mutect2, varscan2
- FOCAD | c.610C>G p.Q204E | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV100620597; called by muse, mutect2, varscan2
- FSHR | c.1013G>A p.C338Y | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100437669; called by muse, mutect2, varscan2
- ID4 | c.485G>C p.*162Sext*10 | Nonstop Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as COSV101099548; called by muse, mutect2, varscan2
- MORC4 | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99717449; called by muse, mutect2, varscan2
- OR10AG1 | c.780G>T p.R260S | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV100400152, COSV56634119, COSV56634644; called by mutect2, varscan2
- OR52A1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100200538; called by muse, mutect2, varscan2
- OR5M1 | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101591587; called by muse, mutect2, varscan2
- SALL2 | c.1542G>A p.M514I | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.561); catalogued as COSV100444521; called by muse, mutect2, varscan2
- SLCO2B1 | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs1469722445, COSV99214947; called by muse, mutect2
- SPATA31D1 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.491); catalogued as rs184147253; called by muse, mutect2, varscan2
- TLR7 | c.1938C>G p.F646L | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101028022; called by muse, mutect2, varscan2
- TMEM143 | c.1285G>A p.G429R | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs141028740; called by muse, mutect2, varscan2
- TNRC6A | c.1406C>T p.S469L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV59369073; called by muse, mutect2, varscan2
- TPBG | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100869795, COSV63882477; called by muse, mutect2, varscan2
- TRBV19 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs78434792; called by muse, mutect2
- TTK | c.1211C>G p.S404* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV100036464; called by muse, mutect2, varscan2
- YES1 | c.64C>G p.P22A | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs770153511, COSV58850067; called by muse, mutect2
- ZFC3H1 | c.4855G>A p.E1619K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.275); catalogued as COSV101110637; called by muse, mutect2, varscan2
- LTBP1 | c.4513dup p.R1505Kfs*7 (on ENST00000404816 / NM_206943.4; = p.R1179Kfs*7 on NM_000627.4) | Frame Shift Ins (INS) | VAF 11/36 reads (31%) | called by mutect2, varscan2
- PRAMEF10 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, varscan2
- SUPT20HL1 | c.1837G>A p.V613M | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NR0B1 | c.1308G>A p.L436= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV100973566; called by muse, mutect2, varscan2
- PLXNA2 | c.1911G>A p.L637= | Silent (SNP) | VAF 67/195 reads (34%) | catalogued as COSV100885668, COSV65443099; called by muse, mutect2, varscan2
- RBM43 | c.396G>A p.L132= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV100508617; called by muse, mutect2, varscan2
- SALL2 | c.1821G>A p.V607= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV100444519; called by muse, mutect2, varscan2
- TDRD7 | c.2994A>G p.E998= | Silent (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
